Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8I4, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8I4-01A (Primary Tumor).

[page 1 of 4]
(188.0cm 112.9kg BSA: 2.43m²)

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) ANTERIOR LYMPH NODE:
Fibroadipose tissue, no lymph node tissue or tumor present.
- (B) ANTERIOR APEX (INK AT MARGIN):
Skeletal muscle and prostate glands, no tumor present.
Inked margin free of prostatic glands.
- (C) LEFT PELVIC LYMPH NODES:
METASTATIC CARCINOMA IN ONE OF ELEVEN LYMPH NODES (1/11), (3.0 MM FOCUS).
No extranodal extension present.
- (D) RIGHT PELVIC LYMPH NODES:
Four lymph nodes, no tumor present (0/4).
- (E) PROSTATE AND SEMINAL VESICLES (INK AT FS MARGIN):
Supplemental report to follow.

Entire report and diagnosis completed by

ESCE *ICD0-3*
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
W 11/24/13

GROSS DESCRIPTION

- (A) ANTERIOR LYMPH NODE - A piece of fibroadipose tissue (3.0 x 2.0 x 0.6 cm). No definitive lymph nodes are identified within the adipose tissue. The specimen is entirely submitted for microscopic examination on A1-A3.
- (B) ANTERIOR APEX - A piece of tan-pink soft tissue (0.6 x 0.2 x 0.2 cm) with one edge inked by the surgeon to indicate true margin. This edge is reinked blue and the specimen is submitted entirely on edge in B for frozen section diagnosis.
*FS/DX: BENIGN GLANDULAR EPITHELIUM. NO CARCINOMA OR GLANDS PRESENT AT INKED MARGIN.
- (C) LEFT PELVIC LYMPH NODES - A 6.7 x 4.5 x 1.0 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal twelve possible lymph nodes ranging from 0.2 x 0.2 x 0.2 cm - 6.5 x 2.0 x 0.5 cm.
SECTION CODE: C1, two possible lymph nodes; C2, four possible lymph nodes; C3, two possible lymph nodes; C4, one possible lymph node bisected; C5, one possible lymph node serially sectioned; C6, C7, one possible lymph node serially sectioned; C8-C11, one possible lymph node serially sectioned.
- (D) RIGHT PELVIC LYMPH NODES - A 5.5 x 4.7 x 1.1 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal four possible lymph nodes ranging from 0.3 x 0.3 x 0.2 cm - 9.4 x 2.0 x 0.5 cm.
SECTION CODE: D1, one possible lymph node; D2, one possible lymph node bisected; D3-D5, one possible lymph node serially sectioned; D6-D11, one possible lymph node serially sectioned.
- (E) PROSTATE AND SEMINAL VESICLES (INK AT FS MARGIN) - Supplemental report to follow.

CLINICAL HISTORY

None given.

SNOMED CODES

[page 2 of 4]
Page: 2

[REDACTED] (188.0cm 112.9kg BSA: 2.43m²)

Specimen Date/Time: [REDACTED]

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 3 of 4]
(188.0cm 112.9kg BSA: 2.43m²)

Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

- (E) PROSTATE AND SEMINAL VESICLES (INK AT F.S. MARGIN):
PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4+3) WITH TERTIARY GLEASON GRADE 5 COMPONENT. (SEE COMMENT)
TUMOR INVADING LEFT SEMINAL VESICLE.
TUMOR EXTENDING FOCALLY INTO EXTRAPROSTATIC TISSUE.
MARGINS OF RESECTION FREE OF TUMOR.
VASCULAR/LYMPHATIC INVASION PRESENT.
PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH-GRADE.
Right seminal vesicle and segments of vasa deferentia, no tumor present.
SEE PREVIOUS REPORT FOR DIAGNOSIS OF PELVIC LYMPH NODES.

COMMENT

The prostate gland contains three separate foci of prostatic adenocarcinoma, one on the transition zone and two in the peripheral zone. The dominant tumor focus although not the one of the highest histologic grade (Gleason score 7/3+4) is located in the left transition zone. This tumor focus measures 2.0 x 1.0 cm in the largest cross-sectional dimension, and it is present in one cross section and extensively in the apex and base regions. This tumor focus invades the left seminal vesicle including intra and extraprostatic portions. Focal extraprostatic extension is present in the left superior neurovascular bundle region. The extent of extraprostatic tumor is less than 1.0 mm. The extraprostatic tumor is present in a perineural location. The second tumor focus and the one of the highest histologic grade (7/4+3 with tertiary Gleason grade 5) is located in the left lateral, left posterolateral, left posterior, mid posterior and right posterior peripheral zone. This tumor focus measures 1.7 x 1.2 cm in the largest cross-sectional dimension, and it is present in the single cross section of the prostate and extensively in the apex and base regions. The third tumor focus is located in the right lateral peripheral zone, exclusively in the apical region. This tumor focus measures 1.0 x 0.2 cm in the largest cross-sectional dimension and it is present in two apical sections. Tumor foci #1 and 2 are confined to the prostate. The margins of resection are free of tumor.

Please refer to the previous report for the diagnosis of the pelvic lymph nodes.

GROSS DESCRIPTION

- (E) PROSTATE AND SEMINAL VESICLES (INK AT F.S. MARGIN) – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

[page 4 of 4]
(188.0cm 112.9kg BSA: 2.43m²)

Specimen Date/Time:

The prostate gland (3.5 x 2.7 x 3.7 cm, 35 grams, post-fixation) has the usual shape. The soft tissue present on the left posterolateral aspect of the prostate appears slightly more abundant than along the right side. A nodule is palpated on the left base of the prostate. Serial cross sections after fixation do not demonstrate carcinoma.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: E1-E3, right seminal vesicle and segment of right vas deferens from the base towards the tip; E4-E6, left seminal vesicle and segment of left vas deferens from the base towards the tip; E7, prostatic base right border; E8, E9, prostatic base right posterior border; E13, prostatic base left border; E14-E16, prostatic base left posterior border; E17-E22, apex anterior; E23, E24, apex left; E25-E28, apex posterior; E29-E32, apex right; E33, detached portions of margin of resection according to specimen radiograph; E34-E37, sections of the single cross section of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (E18-E24) and orange ink denote surfaces on the anterior apical region (reinked) and anterior surface of the prostate which do not represent the true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by:

-----END OF REPORT-----

ICD-9 Discrepancy		✓

Source: NCI Genomic Data Commons file 195a020e-f75b-4883-8b42-6190847d136b (TCGA-KK-A8I4.633E280A-24F4-49FF-95B8-DDA5F447480E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).